Surgical pathology report (de-identified scan), TCGA case TCGA-EO-A2CH, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University Health Network, specimen TCGA-EO-A2CH-01A (Primary Tumor).

[page 1 of 3]
y

Surgical Pathology Consultation Report

ICD-0-3

Carcinoma, serous, NOS 8441/3

Site: endometrium C54.1 w 4/20/11

Site-A Discrepancy		X
Qualifying Synchronous Primary Noted		X

Specimen(s) Received

1. Omentum: omentum
2. Uterus: Uterus, cervix, bilateral salpingo-oophorectomy

Diagnosis

1. Omentum, partial omentectomy:
- Mature adipose tissue, negative for malignancy.
2. Uterus, cervix, bilateral fallopian tubes and ovaries, Total abdominal hysterectomy and bilateral salpingo-oophorectomy:

Endometrium:

- ~~UTERINE SEROUS CARCINOMA~~ (Please see synoptic report)
- Background of atrophy.

Myometrium:

- Invaded by endometrial adenocarcinoma, extending to outer half, 0.9 mm from serosal surface.

Cervix:

- Glandular involvement by endometrial adenocarcinoma.

Right & left ovaries:

- Epithelial inclusion cysts.

Right & left fallopian tubes:

- No histological abnormality.

Synoptic Data

----- MACROSCOPIC -----
Specimen Type: Total Hysterectomy
Tumor Site: Fundus
Tumor Size: Greatest dimension: 0 cm

[page 2 of 3]
Other Organs Present:	Right ovary Left ovary Right fallopian tube Left fallopian tube Omentum
----- MICROSCOPIC -----	
Histologic Type:	Serous adenocarcinoma
Histologic Grade:	Not applicable
Myometrial Invasion:	Invasion Present Greater than 50% myometrial invasion
Cervix Involvement:	Glandular involvement of endocervix
LUS Involvement:	Yes
Venous/Lymphatic Invasion:	Absent
Nodal Involvement:	No nodes submitted
Margins:	Uninvolved by invasive carcinoma
Primary Tumor (pT):	pT3b (IIIB): Involvement of vagina (direct extension or metastasis), rectal or bladder wall (without mucosal involvement), or pelvic wall(s) (frozen pelvis)
Regional Lymph Nodes (pN):	pN0: No regional lymph node metastasis Number of regional lymph nodes examined: 0 Number of regional lymph nodes involved: 0
Distant Metastasis (pM):	pMX: Distant metastasis cannot be assessed
Additional Pathologic Findings:	Other: atrophy
NeoAdjuvant Treatment:	No
Collaborative Staging Extension:	Not applicable

Comment

The pathologic and clinical staging is based on the presence of tumor in the previous vaginal biops

Electronically

verified by:

Gross Description

1. The specimen labeled with the patient's name and as "Omentum: Omentum". It consists of a large unoriented segment of omentum, measuring 24.0 x 10.0 x 1.5 cm (weighing 103.2 g-fresh). Cross-sections appear homogeneously yellow-tan and focally hemorrhagic. No distinct nodules or tumors are grossly identified.
1A-1E representative sections submitted

2. The specimen, labeled with the patient's name and as "Uterus: Uterus, cervix, bilateral salpingo-oophorectomy". The specimen is received fresh and subsequently placed in 10% buffered formalin. It consists of a uterus with attached cervix, bilateral ovaries and fallopian tubes; weighing 128.9 g (fresh). The body of the uterus is slightly distorted and measures 9.0 cm SI x 5.5 cm ML x 5.2 cm AP. The serosal surface is pink-tan, focally hemorrhagic and smooth. The cervix has a maximum diameter of 2.0 cm. The cervical Os measures 0.4 cm in maximum diameter and has a "slit-like" shape. The uterus is bivalved. Both endo/myometrial layers are not of uniform thickness. There is a large tumor occupying the entire endometrial cavity, measuring 8.7 cm SI x 4.5 cm ML x 5.0 cm AP. The tumor extends from the endometrial cavity to the lower

[page 3 of 3]
uterine segment and towards the exocervix. Gross invasion into the myometrium is identified. The cut surface of the tumor appears pale-tan, focally hemorrhagic and partially necrotic. The distance from the tumor to the closest margins are as follows: 1.4 cm from the anterior exocervix, 0.9 cm from the posterior exocervix and <0.1 cm from the closest serosal surface (posterior aspect). The cervical canal is patent and shows small amounts of mucoid material. The cervix reveals a few Nabothian cysts, the largest measuring 0.2 cm in diameter. All of the Nabothian cysts are filled with tan gelatinous material. The right ovary measures 2.0 x 1.1 x 0.9 cm. The surface of the right ovary appears tan and slightly nodular. Cross sections show corpus albicans. Within the right parovarian tissue, one poorly defined nodule is identified measuring 0.4 x 0.3 x 0.3 cm. The cut surface of the nodule appears homogeneously white, solid and firm. The right fallopian tube measures 5.0 cm in length x 0.7 cm in diameter. The surface of the right fallopian tube appears pink-tan and smooth, showing one para tubular cyst measuring 0.2 cm in maximum dimension (filled with white milky fluid). Cross sections appear pale-tan and grossly unremarkable. The left ovary measures 1.9 x 1.1 x 0.8 cm. The surface of the left ovary appears tan and slightly nodular. Cross sections show corpus albicans. The left fallopian tube measures 5.5 cm in length x 0.6 cm in diameter. The surface of the left fallopian tube appears pink-tan and smooth. Cross sections appear pale-tan and grossly unremarkable. Multiple sections from both ovaries/ fallopian tubes, as well as two pieces of the endometrial tumor have been taken for tissue banking. Representative sections are submitted as follows:

- 2A section of left ovary/fallopian tube, previously submitted by research PA
- 2B section of right ovary/fallopian tube, previously submitted by research PA
- 2C endometrial tumor (posterior aspect), previously submitted by research PA
- 2D right fimbria, longitudinally bisected
- 2E sections of right fallopian tube, adjacent to tissue banking
- 2F-2G remainder of right fallopian tube, EIT
- 2H nodule within right parovarian tissue, bisected and EIT
- 2I sections of right ovary, adjacent to tissue banking
- 2J-2L remainder of right ovary, EIT
- 2M left fimbria, longitudinally bisected
- 2N sections of left fallopian tube, adjacent to tissue banking
- 2O-2P remainder of left fallopian tube, EIT
- 2Q sections of left ovary, adjacent to tissue banking
- 2R-2T remainder of left ovary, EIT
- 2U-2Y a full thickness/transverse section of endo/myometrium, including endometrial tumor, anterior aspect (blocks 2V-2W and 2X-2Y each contains a bisected section)
- 2Z-2AB a full length/partial thickness section of endo/myometrium, including endometrial tumor, from endometrial cavity to exocervix, anterior aspect
- 2AC tumor with closest serosal surface, anterior aspect (adjacent to the fundus)
- 2AD-2AF a partial thickness/transverse section of endo/myometrium, including endometrial tumor, posterior aspect
- 2AG-2AJ a full length/partial thickness section of endo/myometrium, including endometrial tumor, from endometrial cavity to exocervix, posterior aspect
- 2AK tumor with closest serosal surface, posterior aspect (adjacent to the fundus)

Source: NCI Genomic Data Commons file 1572779f-f0fb-4175-97da-7652a0450ff0 (TCGA-EO-A2CH.B4A5577E-C043-4D25-8D53-77A43C5EC0CC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).